Gene-level copy-number profile of tumor specimen ALCH-B003-TTP1-A from ALCHEMIST case ALCH-B003, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.1 years (20,130 days).
Specimen ALCH-B003-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2dd323a6-894b-4d5a-afc6-da56193e42b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B003-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/2ac00e20-f1d9-4078-91ce-66fee0f9ff46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 357; copy number 2: 57,908; copy number 3: 73; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,586,491–2,591,469, 1 gene (within-gene range 0–2): PRXL2B.
- chr5:144,087–144,197, 1 gene (within-gene range 0–2): Y_RNA.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,912,276, 35 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5.
- chr15:78,749,833–78,811,464, 3 genes (within-gene range 0–2): AC022748.3, AC022748.1, ADAMTS7.
- chr16:629,239–667,833, 6 genes (within-gene range 0–2): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:74,408,270–74,421,953, 1 gene: CLEC18B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,635,180–15,644,330, 1 gene, copy number 6: MED15P7.

Autosomal genes at a single copy (total copy number 1): 357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
